Somatic mutation profile of tumor specimen MP2PRT-PANXLR-TMP1-A (aliquot MP2PRT-PANXLR-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANXLR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (719 days).
Specimen MP2PRT-PANXLR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21db8622-ea1c-4545-a3e4-e856bbbac3cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANXLR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANXLR-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5139b5bc-b6c6-4ae4-afa4-06bc0ea70b3b

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV104379009; called by muse, mutect2
- KSR2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 171/731 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56667168; called by muse, mutect2, varscan2
- SULT4A1 | c.508+1G>A p.X170_splice | Splice Site (SNP) | VAF 26/147 reads (18%) | catalogued as rs1300942161; called by muse, mutect2, varscan2
- GABRR3 | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MATN4 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 26/690 reads (4%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- TSHZ2 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BICRAL | c.219T>C p.S73= | Silent (SNP) | VAF 32/450 reads (7%) | called by muse, mutect2
- C4orf17 | c.774C>A p.P258= | Silent (SNP) | VAF 28/309 reads (9%) | called by muse, mutect2
- IGF2BP2 | c.1458C>T p.F486= | Silent (SNP) | VAF 20/380 reads (5%) | catalogued as COSV60486173; called by muse, mutect2
- KRT20 | c.246G>A p.A82= | Silent (SNP) | VAF 65/552 reads (12%) | catalogued as rs753053653, COSV51424844; called by muse, mutect2, varscan2
- NLRP7 | c.210G>A p.A70= | Silent (SNP) | VAF 88/443 reads (20%) | catalogued as rs111764628, COSV60177080; called by muse, mutect2, varscan2
- PHF2 | c.2043G>A p.S681= | Silent (SNP) | VAF 23/460 reads (5%) | catalogued as rs549516534; called by muse, mutect2
